Somatic mutation profile of tumor specimen TCGA-ZJ-AAXD-01A (aliquot TCGA-ZJ-AAXD-01A-21D-A42O-09) from TCGA case TCGA-ZJ-AAXD, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 35.5 years (12,968 days).
Specimen TCGA-ZJ-AAXD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5cc0008f-2ebc-408a-b546-0505dc33765f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZJ-AAXD-10A (Blood Derived Normal), aliquot TCGA-ZJ-AAXD-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6597ffa-f57a-4858-a98b-94a87a997771

The open-access MAF lists 94 somatic variants for this specimen: 69 protein-altering or splice-affecting, 25 silent.
By variant classification: Missense Mutation 63, Silent 25, Nonsense Mutation 5, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 72/133 reads (54%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.11899C>G p.Q3967E | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV101447149; called by muse, mutect2, varscan2
- ABHD17A | c.736C>T p.P246S (on ENST00000292577 / NM_001130111.2; = p.P297S on NM_031213.4) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs773838028, COSV99171346; called by muse, mutect2, varscan2
- AGAP2 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); catalogued as rs1027073679, COSV99224034; called by muse, mutect2, varscan2
- ASAH2 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 13/27 reads (48%) | catalogued as rs756730469, COSV100270070; called by muse, mutect2, varscan2
- CASP8 | c.435G>C p.E145D (on ENST00000432109 / NM_033355.3; = p.E177D on NM_001228.4) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99965773; called by muse, mutect2, varscan2
- CCDC78 | c.282G>C p.E94D | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as rs200446394, COSV99285117; called by muse, varscan2
- CCN3 | c.227C>G p.S76* | Nonsense Mutation (SNP) | VAF 6/10 reads (60%) | catalogued as COSV99423274; called by muse, mutect2, varscan2
- CDHR3 | c.50G>C p.G17A | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.138); catalogued as COSV100488747, COSV58420724; called by muse, mutect2, varscan2
- CDK12 | c.392A>G p.E131G | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.968); catalogued as rs1385240822, COSV101420513; called by muse, mutect2, varscan2
- CSF2RA | c.183C>G p.F61L | Missense Mutation (SNP) | VAF 9/269 reads (3%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100817908; called by muse, mutect2
- CTDSPL2 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV99527169; called by muse, mutect2, varscan2
- DLGAP1 | c.2605G>T p.D869Y | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100233053, COSV59835247; called by muse, mutect2, varscan2
- DMBT1 | c.5243C>T p.P1748L (on ENST00000338354 / NM_001377530.1; = p.P991L on NM_004406.3) | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV100353900; called by muse, mutect2, varscan2
- DYNC1I1 | c.703G>C p.D235H | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV100268989; called by muse, mutect2, varscan2
- EMG1 | c.222G>T p.L74F | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV99781271; called by muse, mutect2, varscan2
- ERCC6L2 | c.600C>G p.F200L | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV99998905; called by muse, mutect2, varscan2
- FAM160B1 | c.1432C>G p.L478V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100985555; called by muse, mutect2, varscan2
- GABRP | c.319C>G p.L107V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.361); catalogued as COSV54664530, COSV99517043; called by muse, mutect2, varscan2
- GPR37L1 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.388); catalogued as COSV99693375; called by muse, mutect2, varscan2
- HBE1 | c.203T>C p.V68A | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV99496368; called by muse, mutect2, varscan2
- IFT140 | c.3577G>C p.E1193Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.178); catalogued as COSV100794477; called by muse, mutect2, varscan2
- IGFLR1 | c.119G>A p.S40N | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.215); catalogued as rs1352774727, COSV99495383; called by muse, mutect2, varscan2
- IGSF10 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.69); catalogued as rs753021169, COSV56785057; called by muse, mutect2, varscan2
- IRAG1 | c.2253T>G p.N751K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.691); catalogued as COSV101351551; called by muse, mutect2, varscan2
- ITGA10 | c.3487G>C p.E1163Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100995004; called by muse, mutect2, varscan2
- KAT6B | c.2722A>T p.S908C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99768804; called by muse, mutect2, varscan2
- KCNB2 | c.2373G>T p.Q791H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.641); catalogued as COSV101578938, COSV73050386; called by muse, mutect2, varscan2
- KRT6A | c.65C>A p.S22* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as COSV99043602; called by muse, mutect2, varscan2
- LIG3 | c.2588C>G p.S863C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as COSV99253009; called by muse, mutect2, varscan2
- LMX1B | c.347G>C p.S116T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.874); catalogued as COSV100827261; called by muse, mutect2, varscan2
- MICALL2 | c.460C>G p.P154A | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV99876203; called by muse, mutect2, varscan2
- MOCS3 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99724461; called by muse, mutect2, varscan2
- MRPS30 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs749274124, COSV101539283; called by muse, mutect2, varscan2
- NBR1 | c.2672C>T p.S891F | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57832139; called by muse, mutect2, varscan2
- NLRC5 | c.5399G>C p.R1800T | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.617); catalogued as COSV99348045; called by muse, mutect2, varscan2
- NLRP4 | c.1411G>T p.D471Y | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV100016903; called by muse, mutect2, varscan2
- OR1A1 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs546921641, COSV100410737, COSV58404896; called by muse, mutect2, varscan2
- PISD | c.661C>T p.P221S (on ENST00000439502 / NM_001326412.1; = p.P187S on NM_014338.3) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV99837358; called by muse, mutect2, varscan2
- PLCH2 | c.3508G>A p.E1170K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.018); catalogued as COSV99616935; called by muse, mutect2, varscan2
- PLK3 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.227); catalogued as rs755159184, COSV59500628; called by muse, mutect2, varscan2
- PRRC2C | c.1451C>T p.A484V (on ENST00000367742; = p.A482V on NM_015172.4) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs868424256, COSV100145820; called by muse, mutect2, varscan2
- PSMD7 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.594); catalogued as COSV99542799; called by muse, mutect2, varscan2
- RFXANK | c.575C>T p.T192M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1393172112, COSV100284592; called by muse, mutect2, varscan2
- RYR3 | c.8936G>A p.R2979Q (on ENST00000389232; = p.R2980Q on NM_001036.6) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as rs200346049, COSV66785492; called by muse, mutect2, varscan2
- SBF2 | c.4100C>T p.T1367I | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV99815345; called by muse, mutect2
- SLC9A1 | c.1541C>T p.T514M | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as rs902869080, COSV99849950; called by muse, mutect2, varscan2
- SNX32 | c.318G>T p.E106D | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as COSV57449439; called by muse, mutect2, varscan2
- SPRR2E | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.158); catalogued as COSV100907447; called by muse, mutect2, varscan2
- SREBF2 | c.2661G>T p.W887C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63332071; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.486G>T p.R162S | Missense Mutation (SNP) | VAF 20/38 reads (53%) | PolyPhen benign (0.241); catalogued as COSV100081980; called by muse, mutect2, varscan2
- STK39 | c.562C>G p.Q188E | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1311483244, COSV100597099; called by muse, mutect2, varscan2
- STON2 | c.2627C>T p.S876F (on ENST00000649389 / NM_001366849.2; = p.S819F on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201092611, COSV99965065; called by muse, mutect2, varscan2
- SYNCRIP | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100784305; called by muse, mutect2, varscan2
- SYNDIG1 | c.63G>C p.K21N | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV100965397, COSV65240248; called by muse, mutect2, varscan2
- TENT5D | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867317346, COSV100382904; called by muse, mutect2, varscan2
- TEX15 | c.4292C>G p.S1431C (on ENST00000256246; = p.S1814C on NM_001350162.2) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV99821932; called by muse, mutect2, varscan2
- TMTC3 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99898593; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100709164; called by muse, mutect2, varscan2
- UBE2O | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.058); catalogued as rs369070451; called by muse, mutect2, varscan2
- UBE2V2 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV101568647; called by muse, mutect2, varscan2
- UBR5 | c.6878G>A p.R2293Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55300395; called by muse, mutect2, varscan2
- USP13 | c.1586G>A p.R529K | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.216); catalogued as COSV55863386; called by muse, mutect2, varscan2
- VPS9D1 | c.1255G>A p.V419I | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769766323, COSV66993818; called by muse, mutect2, varscan2
- WDR90 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs979915131, COSV99553995; called by muse, mutect2, varscan2
- ZC3H18 | c.2374C>T p.Q792* | Nonsense Mutation (SNP) | VAF 35/52 reads (67%) | catalogued as COSV99964361; called by muse, mutect2, varscan2
- ZNF350 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.198); catalogued as COSV99702658; called by muse, mutect2, varscan2
- CCL14 | c.244T>C p.W82R (on ENST00000618404 / NM_032963.4; = p.W98R on NM_032962.4) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, varscan2
- SCFD1 | c.909_910del p.P304Sfs*4 | Frame Shift Del (DEL) | VAF 35/154 reads (23%) | called by pindel, varscan2
- ANK1 | c.3477G>C p.P1159= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV55879650, COSV99226480; called by muse, mutect2, varscan2
- AOC2 | c.567C>T p.I189= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99513746; called by muse, mutect2, varscan2
- CARD14 | c.1341C>T p.L447= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs752765870, COSV100712607; called by muse, mutect2, varscan2
- CFC1 | c.132G>A p.Q44= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV99383508; called by muse, mutect2, varscan2
- DNAH5 | c.12831T>C p.F4277= | Silent (SNP) | VAF 6/91 reads (7%) | catalogued as COSV99452925; called by muse, mutect2
- ITK | c.1071G>A p.V357= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV101439854; called by muse, mutect2
- KAT5 | c.384C>T p.G128= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs1356909094, COSV100384032; called by muse, mutect2, varscan2
- KAT6B | c.2721G>A p.K907= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV99768803; called by muse, mutect2, varscan2
- KIF4A | c.1873C>T p.L625= | Silent (SNP) | VAF 7/149 reads (5%) | catalogued as COSV100979616; called by muse, mutect2
- LGI3 | c.1548C>T p.F516= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100103250; called by muse, mutect2, varscan2
- LIG3 | c.2430C>T p.I810= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99253006; called by muse, mutect2, varscan2
- LONP1 | c.1620G>C p.L540= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs769736193, COSV100638716; called by muse, varscan2
- NAPSA | c.333C>T p.F111= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs1240669621, COSV99515968; called by muse, mutect2, varscan2
- NSMF | c.465G>A p.Q155= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV52996656; called by muse, mutect2, varscan2
- RAPGEF3 | c.2742C>T p.L914= (on ENST00000389212; = p.L872= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV50197821; called by muse, mutect2
- REEP1 | c.324C>G p.V108= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV99383232; called by muse, mutect2, varscan2
- RHPN2 | c.66G>A p.R22= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV99578131; called by muse, varscan2
- RPL23 | c.147G>A p.L49= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99834757; called by mutect2, varscan2
- RYR1 | c.12654C>T p.F4218= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs1294294978, COSV62094637; called by muse, mutect2, varscan2
- SLITRK2 | c.48C>A p.I16= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV100158109; called by muse, mutect2, varscan2
- SLITRK2 | c.1530C>T p.P510= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as rs1556944542, COSV100158112, COSV59429511; called by muse, mutect2
- SMTN | c.147G>A p.L49= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100294836; called by mutect2, varscan2
- TAF5 | c.1647C>T p.A549= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100674751; called by muse, mutect2, varscan2
- ZNF526 | c.1101C>T p.R367= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as rs1469365551, COSV55898434; called by muse, mutect2, varscan2
- ZNF563 | c.1233C>T p.H411= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs775761108, COSV99536394; called by muse, mutect2, varscan2
